Gene-level copy-number profile of tumor specimen TCGA-33-AASB-01A from TCGA case TCGA-33-AASB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.2 years (24,183 days).
Specimen TCGA-33-AASB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b8e13eb4-2de2-45bf-a2d2-20a96a7586f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-AASB-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/35752b5d-63ed-4148-9387-53602894014d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,900; copy number 2: 24,223; copy number 3: 22,489; copy number 4: 5,321; copy number 5: 3,576; copy number 6: 2,049; copy number 7: 134; copy number 8: 4; copy number 10: 43; copy number 25: 20; copy number 33: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-AASB-01A-11D-A400-01): tumor purity 0.44, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr10:87,659,613–87,863,533, 5 genes: PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.
- chr11:40,114,203–42,253,721, 14 genes (within-gene range 0–2): LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 229 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:123,067,025–123,449,090, 6 genes, copy number 7 (within-gene range 5–7): PDIA5, MIR7110, SEC22A, AC112503.2, ADCY5, AC112503.1.
- chr6:48,701,491–49,078,051, 4 genes, copy number 8: FO393412.1, AL391538.1, AL022099.1, AL589994.1.
- chr8:115,509,602–115,511,325, 1 gene, copy number 7: AF178030.1.
- chr12:24,566,964–27,972,733, 86 genes, copy number 10–33 (broad region; genes not listed).
- chr12:28,163,298–28,319,463, 5 genes, copy number 10: AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P.
- chr20:62,302,093–64,313,132, 127 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,900. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
